Somatic mutation profile of tumor specimen MP2PRT-PATCMH-TBP1-A (aliquot MP2PRT-PATCMH-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATCMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.3 years (1,578 days).
Specimen MP2PRT-PATCMH-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ef70e36-0ce7-4c28-8f7c-8997e399bb39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCMH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCMH-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b08e78cc-e6d6-4c81-be14-c800320e32a9

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 48/607 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2
- ACVR2A | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54019230; called by muse, mutect2, varscan2
- IFI27 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 48/470 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs775606082; called by muse, mutect2, varscan2
- TMEM132D | c.2847G>T p.Q949H | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs754537377; called by muse, mutect2, varscan2
- PER3 | c.1137C>A p.S379R | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2
